CCDI case PBBLDX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/60d2a826-e47f-481a-b6fe-41d9759fd471

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.9 years (3,999 days).

Biospecimens (3 samples)
- Sample 0DBM21: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBM2J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBM2K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
